Gene-level copy-number profile of tumor specimen TARGET-40-0A4I4O-01A from TARGET case TARGET-40-0A4I4O, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 32.4 years (11,828 days).
Specimen TARGET-40-0A4I4O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.4c6fc317-871d-5fde-a76d-4fe0c94f1937.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-0A4I4O-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 398 have no estimate.
https://portal.gdc.cancer.gov/files/2a46f34b-4d37-49c9-a354-f7c14f62ce2b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 3,924; copy number 2: 21,535; copy number 3: 11,460; copy number 4: 12,288; copy number 5: 6,768; copy number 6: 2,548; copy number 7: 85; copy number 8: 315; copy number 9: 283; copy number 10: 506; copy number 12: 35; copy number 13: 99; copy number 14: 62; copy number 15: 140; copy number 18: 1; copy number 20: 60; copy number 23: 99; copy number 24: 8.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–2): AL359922.1.
- chr9:21,892,188–21,995,301, 4 genes: AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.
- chr16:80,179,129–80,180,682, 1 gene: AC022166.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 10,811 genes in 51 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:84,958,989–91,513,775, 45 genes, copy number 5 (within-gene range 2–5): CADM2, MIR5688, CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19, ABBA01000933.1, ABBA01000935.2.
- chr3:135,925,891–137,011,085, 24 genes, copy number 15: AC092989.1, NDUFS6P1, PPP2R3A, AC072039.1, AC072039.2, MSL2, TDGF1P6, AC092991.1, PCCB, STAG1, RNU6-1284P, HMGN1P10, RNU6-789P, AC117382.1, AC117382.2, AC096992.3, AC096992.1, SLC35G2, NCK1-DT, AC096992.2, NCK1, RAD51AP1P1, IL20RB, IL20RB-AS1.
- chr3:138,061,990–138,405,534, 8 genes, copy number 15: DZIP1L, KRT8P36, A4GNT, AC023049.1, DBR1, ARMC8, NME9, MRAS.
- chr3:147,590,996–150,050,788, 56 genes, copy number 5 (within-gene range 2–5): NPM1P28, AC092925.1, AC092958.1, AC092958.4, LINC02032, AC092958.3, AC092958.2, AC025566.1, HNRNPA1P20, LINC02045, LINC02046, AC069410.1, RPL38P1, AGTR1, CPB1, HMGB1P30, AC092979.1, CPA3, AC092979.2, UBQLN4P1, GYG1, HLTF, HLTF-AS1, Y_RNA, MED28P2, HPS3, CP, AC093001.2, CPHL1P, AC093001.1, TM4SF18, AC073522.1, TM4SF1, TM4SF1-AS1, AC108751.4, AC108751.2, AC108751.3, FKBP1AP4, AC108751.1, TM4SF4, AC108751.5, WWTR1, RNU6-1098P, WWTR1-IT1, WWTR1-AS1, COMMD2, ANKUB1, RNU6-507P, RNF13, RNU6-720P, NPM1P29, PFN2, AC117395.1, TMEM183B, PPIAP73, HNRNPA1P24.
- chr5:54,517,759–56,111,329, 43 genes, copy number 6–9 (within-gene range 4–9): SNX18, AC016583.1, AC016583.2, CSPG4BP, AC112198.1, AC112198.3, AC112198.2, ESM1, AC034238.1, GZMK, Y_RNA, AC034238.3, AC034238.2, GZMAP1, GZMA, CDC20B, GPX8, MIR449A, MIR449B, MIR449C, MCIDAS, CCNO, AC026704.1, DHX29, MTREX, AC020728.1, PLPP1, AC010480.1, MIR5687, RNF138P1, AK4P2, SLC38A9, DDX4, AC016632.1, RNA5SP183, HNRNPH1P3, IL31RA, IL6ST, AC008914.1, AC016596.2, AC008892.1, FLJ31104, AC016596.1.
- chr6:18,223,860–20,212,469, 21 genes, copy number 12–18 (within-gene range 1–18): DEK, Y_RNA, AL138825.1, RNU6-263P, DDX18P3, IMPDH1P9, RNF144B, MIR548A1HG, MIR548A1, AL589647.1, AL357052.1, LNC-LBCS, RPL5P20, RNA5SP205, KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL022726.1, AL008627.1, MBOAT1.
- chr6:20,993,474–22,654,455, 14 genes, copy number 7 (within-gene range 1–7): RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15, AL136313.1, RN7SKP240, NBAT1, AL359694.1.
- chr6:26,538,366–30,830,659, 272 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr6:35,342,558–35,728,583, 14 genes, copy number 8 (within-gene range 3–8): PPARD, MKRN6P, FANCE, RPL10A, MIR7111, TEAD3, TULP1, AL033519.4, AL033519.3, FKBP5, AL033519.2, AL033519.5, AL033519.1, MIR5690.
- chr6:37,433,219–48,952,781, 251 genes, copy number 6–20 (within-gene range 3–20) (broad region; genes not listed).
- chr6:49,273,600–51,537,543, 34 genes, copy number 7: FO393413.1, RNU7-65P, EEF1A1P42, MMUT, CENPQ, GLYATL3, C6orf141, CYP2AC1P, RHAG, CRISP2, AL121974.1, AL121950.1, CRISP3, PGK2, AL359458.1, CRISP1, DEFB133, DEFB114, DEFB113, DEFB110, DEFB112, AL138826.1, AL132799.1, AL360175.1, AL135908.1, TFAP2D, TFAP2B, RPS17P5, AL049693.1, FTH1P5, AL158050.2, AL158050.1, AL365219.1, AL445529.1.
- chr6:51,615,299–54,945,099, 78 genes, copy number 8–13 (within-gene range 2–13) (broad region; genes not listed).
- chr6:69,672,757–71,127,105, 23 genes, copy number 6: LMBRD1, NPM1P37, GAPDHP42, COL19A1, RPL37P15, COL9A1, AL160262.1, AL080275.1, AL365226.1, FAM135A-AS1, FAM135A, RNU7-48P, SDHAF4, AL583856.2, AL583856.1, SLC25A6P6, SMAP1, AL354943.1, NDUFAB1P1, B3GAT2, AL096709.1, BECN1P2, U3.
- chr6:89,926,528–90,587,072, 8 genes, copy number 7: BACH2, AL121787.1, RN7SKP110, AL158136.1, AL117342.1, AL132996.1, MIR4464, MAP3K7.
- chr6:106,045,423–108,837,113, 64 genes, copy number 6 (within-gene range 1–6) (broad region; genes not listed).
- chr6:120,015,179–120,706,789, 4 genes, copy number 7: MIR3144, AL096854.1, RNU6-214P, RNA5SP215.
- chr6:129,576,132–130,146,179, 8 genes, copy number 5: ARHGAP18, RPL5P21, AL451046.2, B3GALNT2P1, AL451046.1, TMEM244, L3MBTL3, AL355581.1.
- chr6:135,283,532–136,552,554, 25 genes, copy number 8: AHI1, AL049552.1, AL049552.2, Y_RNA, LINC00271, GAPDHP73, AL035604.1, HMGB1P17, AL133319.1, PDE7B, AL360178.1, AL360178.2, AL138828.1, COX5BP2, AL138828.2, MTFR2, BCLAF1, AL023284.1, AL023284.4, MAP7, AL023284.3, AL023284.2, NDUFS5P1, RN7SKP299, AL024508.1.
- chr6:138,650,226–140,898,381, 28 genes, copy number 6 (within-gene range 4–6): AL590617.1, AL590617.2, CCDC28A-AS1, CCDC28A, ECT2L, ACKR4P1, AL121834.1, REPS1, ABRACL, HECA, AL031772.1, AL158850.1, TXLNB, AL592429.2, AL592429.1, CITED2, LINC01625, ATP5PBP6, AL390205.1, FILNC1, AL050338.1, AL050338.2, AL357146.1, RNA5SP220, MIR3668, AL035446.2, MIR4465, RPS3AP24.
- chr6:145,382,535–150,069,121, 92 genes, copy number 6–10 (within-gene range 3–11) (broad region; genes not listed).
- chr6:160,742,509–161,274,061, 10 genes, copy number 6: AL109933.5, AL109933.4, AL109933.3, AL391361.2, AL391361.1, AL139393.2, AL139393.1, MAP3K4-AS1, MAP3K4, AGPAT4.
- chr7:70,972–151,879,223, 2,896 genes, copy number 5–8 (broad region; genes not listed).
- chr8:66,870,749–142,736,927, 1,071 genes, copy number 6–12 (within-gene range 3–16) (broad region; genes not listed).
- chr10:23,393,405–23,586,224, 4 genes, copy number 6: AL606469.2, OTUD1, AL512603.2, AL512603.1.
- chr11:37,702,125–42,939,998, 29 genes, copy number 5–9: AC061997.1, RPL7AP56, LINC02760, AC103798.1, LRRC6P1, AC021713.1, LINC02759, LINC01493, AC021723.2, AC021723.1, RNU6-99P, AC021749.1, AC021820.1, AC080100.1, LRRC4C, Y_RNA, AC090720.1, RNU6-365P, AC090138.1, LINC02741, AC021006.1, AC021006.2, LINC01499, AC023442.1, AC023442.3, AC023442.2, LINC02745, LINC02740, AC109810.1.
- chr11:54,591,480–58,005,705, 178 genes, copy number 5–12 (broad region; genes not listed).
- chr12:42,081,845–42,967,353, 22 genes, copy number 5: GXYLT1, YAF2, PPHLN1, AC020629.1, ZCRB1, MIR7851, SNORA74, AC079684.1, RNU6-249P, AC079601.2, Y_RNA, PRICKLE1, AC079601.1, AC079600.3, LINC02402, AC079600.2, AC079600.1, LINC02451, RPS27P21, LINC02450, AC068802.1, AC012038.2.
- chr13:18,467,172–21,179,084, 94 genes, copy number 5–6 (broad region; genes not listed).
- chr13:78,488,182–85,148,121, 54 genes, copy number 5–8: ELOCP23, AL445209.1, POU4F1, OBI1, RPL21P111, LINC00331, HSPD1P8, CCT5P2, NIPA2P5, BCAS2P3, RBM26, RNA5SP33, RBM26-AS1, NDFIP2-AS1, NDFIP2, LINC01068, AL136442.1, LINC01038, LINC00382, AL158064.1, LINC01080, AL137781.1, SPRY2, RNU6-61P, HNRNPA1P31, PWWP2AP1, AL590807.1, ARF4P4, LINC00377, DPPA3P3, LINC00564, AL353633.1, RNU6-77P, HIGD1AP2, PTMAP5, AL445255.1, GYG1P2, AL512782.1, RNU6-67P, AL353688.1, SLITRK1, AL355481.1, VENTXP2, AL590681.1, UBE2D3P4, AL445604.1, AL162493.1, MTND4P1, MTND5P3, LINC00333, AL445588.1, AL356313.1, LINC00375, AL160154.1.
- chr14:18,333,726–26,208,424, 484 genes, copy number 6 (broad region; genes not listed).
- chr14:30,370,108–43,596,683, 200 genes, copy number 6 (broad region; genes not listed).
- chr14:45,110,883–69,804,331, 477 genes, copy number 6 (within-gene range 6–10) (broad region; genes not listed).
- chr14:75,423,683–76,501,837, 22 genes, copy number 6: AF111167.2, JDP2, BATF, AC007182.1, FLVCR2, AC007182.2, RNA5SP387, AC007182.3, TTLL5, ERG28, AF107885.2, AF107885.1, IFT43, TGFB3, TGFB3-AS1, AC008015.1, AC016526.4, GPATCH2L, AC016526.2, AC016526.3, AC016526.1, ESRRB.
- chr15:19,878,555–50,182,817, 918 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr15:53,419,865–101,933,350, 1,213 genes, copy number 5 (broad region; genes not listed).
- chr16:30,875,222–35,912,516, 285 genes, copy number 6 (broad region; genes not listed).
- chr17:7,686,071–10,815,164, 110 genes, copy number 6–9 (within-gene range 4–9) (broad region; genes not listed).
- chr17:12,665,890–22,706,703, 425 genes, copy number 6–24 (broad region; genes not listed).
- chr18:77,863,464–78,140,887, 5 genes, copy number 20: RNA5SP461, LINC01029, AC134978.1, RNU6-655P, AC107892.1.
- chr22:16,405,330–44,862,706, 1,183 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,537. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
